Somatic mutation profile of tumor specimen TCGA-HC-8216-01A (aliquot TCGA-HC-8216-01A-11D-A29Q-08) from TCGA case TCGA-HC-8216, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.7 years (21,428 days).
Specimen TCGA-HC-8216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9500e3f4-890e-4b5f-ba7e-2c7b6a4bf2e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8216-10A (Blood Derived Normal), aliquot TCGA-HC-8216-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ca50c99-78cf-4bfc-a985-a89a274c0e90

The open-access MAF lists 88 somatic variants for this specimen: 70 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 61, Silent 18, Nonsense Mutation 5, Splice Site 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.421T>G p.C141G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519978, COSV52675559, COSV52751154, COSV52796306, COSV53037181; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG6 | c.766G>T p.V256F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV51591710; called by muse, mutect2
- AHNAK | c.11848C>T p.P3950S | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs951778803, COSV57212779; called by muse, mutect2
- AMDHD1 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57137919, COSV57138679; called by muse, mutect2, varscan2
- ANK1 | c.5060C>T p.P1687L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as COSV55881000; called by muse, mutect2
- ANKLE1 | c.766A>G p.K256E (on ENST00000394458; = p.K202E on NM_152363.6) | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV63920645; called by muse, mutect2
- ARC | c.1160C>T p.S387F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV63078475; called by muse, mutect2, varscan2
- ARSL | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.543); catalogued as COSV66965225; called by muse, mutect2
- ATP11B | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV60028394; called by muse, mutect2
- ATP11B | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV60028415; called by muse, mutect2
- CD5L | c.478T>A p.Y160N | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100941061, COSV63821924; called by muse, mutect2, varscan2
- CD83 | c.289A>C p.T97P | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64788123; called by muse, mutect2
- CELF2 | c.757C>A p.L253I (on ENST00000416382 / NM_001025077.3; = p.L260I on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV59973488; called by muse, mutect2, varscan2
- CHD7 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.785); catalogued as COSV71110118; called by muse, mutect2, varscan2
- CPNE9 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1189887209, COSV56068393; called by muse, mutect2
- CREB3L3 | c.841C>G p.Q281E | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV50195391; called by muse, mutect2
- DAW1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs761247524, COSV59365270; called by muse, mutect2, varscan2
- EEF2 | c.149G>C p.R50P | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV58579395; called by muse, mutect2, varscan2
- GLDC | c.2259C>A p.H753Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58679773; called by muse, mutect2
- HDLBP | c.1402T>G p.S468A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.051); catalogued as COSV60495385; called by muse, mutect2
- HIPK3 | c.2583C>A p.D861E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV57562414; called by muse, mutect2
- HSD11B1 | c.89-1G>C p.X30_splice | Splice Site (SNP) | VAF 8/102 reads (8%) | catalogued as COSV54827139; called by muse, mutect2
- IL9 | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50853392; called by muse, mutect2, varscan2
- KDM2A | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 29/222 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV67081990; called by muse, mutect2, varscan2
- KMT2D | c.7589C>T p.T2530I | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs773982820, COSV56419493, COSV56437873; ClinVar: likely benign; called by mutect2, varscan2
- KRT23 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV52927376, COSV52927677; called by muse, mutect2, varscan2
- KRT75 | c.1383-1G>T p.X461_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | catalogued as rs1368985388, COSV52872669; called by muse, mutect2, varscan2
- LZTR1 | c.1942+2T>G p.X648_splice | Splice Site (SNP) | VAF 10/113 reads (9%) | catalogued as rs752489470, COSV53147357; called by muse, mutect2
- MKS1 | c.1061T>G p.V354G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV56596329; called by muse, mutect2, varscan2
- MTHFD1L | c.1027C>T p.H343Y | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV66209643; called by muse, mutect2, varscan2
- MYH13 | c.1325T>A p.V442D | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52828036; called by muse, mutect2
- MYLK2 | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs766074380, COSV65659007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK2 | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV65659014; called by muse, mutect2, varscan2
- NAGK | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.889); catalogued as COSV54903520; called by muse, mutect2, varscan2
- NALCN | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs369137916; called by muse, mutect2, varscan2
- NEO1 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767605567, COSV56070916; called by muse, mutect2, varscan2
- OCM2 | c.320T>C p.V107A | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57535405; called by muse, mutect2, varscan2
- OR10Q1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57470410; called by muse, mutect2
- OR13C5 | c.638T>A p.L213* | Nonsense Mutation (SNP) | VAF 9/195 reads (5%) | catalogued as COSV66164566; called by muse, mutect2
- OTOA | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV53753646, COSV53757327; called by muse, mutect2
- OTOGL | c.5666T>C p.L1889P (on ENST00000547103; = p.L1880P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54014201, COSV54016539; called by muse, mutect2
- PLAT | c.925T>A p.F309I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV54275506; called by muse, mutect2
- PLXNA1 | c.4807A>G p.K1603E | Missense Mutation (SNP) | VAF 13/231 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52524445; called by muse, mutect2
- PRB3 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777254866, COSV54389845; called by muse, mutect2, varscan2
- PRSS22 | c.920C>A p.P307Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV50721617; called by muse, mutect2
- RAD51AP2 | c.3179A>G p.E1060G | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV67588013; called by muse, mutect2
- RHNO1 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as rs756533975, COSV63485329; called by muse, mutect2
- RYR3 | c.5938C>T p.R1980* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV66786061, COSV66809822; called by muse, mutect2, varscan2
- SALL1 | c.2327C>T p.T776M | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745310317, COSV51757148, COSV51758411; called by muse, mutect2, varscan2
- SEC16B | c.1196A>T p.Y399F | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV57625445; called by muse, mutect2, varscan2
- SELP | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.674); catalogued as COSV55251681; called by muse, mutect2, varscan2
- SEMA3E | c.596A>G p.D199G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57089394; called by muse, mutect2, varscan2
- SGMS1 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs1419435896, COSV62369191, COSV62370392, COSV62374188; called by muse, mutect2
- SMC3 | c.2535+1G>C p.X845_splice | Splice Site (SNP) | VAF 3/54 reads (6%) | catalogued as COSV62420100; called by muse, mutect2
- SOBP | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57998094; called by muse, mutect2
- SPTA1 | c.6631C>T p.R2211C | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs773800556, COSV63752742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SSMEM1 | c.223A>T p.T75S | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52833454; called by muse, mutect2
- STAB2 | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV66338702; called by muse, mutect2, varscan2
- TECTA | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50705953; called by muse, mutect2
- TMEM71 | c.535A>G p.K179E (on ENST00000523829 / NM_001382398.1; = p.K160E on NM_144649.3) | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV63457299; called by muse, mutect2
- TOP3A | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58175380, COSV58177243; called by muse, mutect2, varscan2
- TRPM6 | c.3285C>A p.Y1095* | Nonsense Mutation (SNP) | VAF 6/133 reads (5%) | catalogued as COSV62509592; called by muse, mutect2
- UGT2B11 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1291874340, COSV71423340; called by muse, mutect2
- VPS13C | c.7242T>A p.F2414L (on ENST00000644861 / NM_020821.3; = p.F2371L on NM_017684.5) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.101); catalogued as COSV51175763; called by muse, mutect2, varscan2
- WDR33 | c.2511G>T p.Q837H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV59248658; called by muse, mutect2, varscan2
- WSCD2 | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV54582427, COSV54592039; called by muse, mutect2
- ZBTB9 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1391426171, COSV67702016; called by muse, mutect2, varscan2
- ZFP42 | c.746T>G p.F249C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58817341; called by muse, mutect2, varscan2
- ZFYVE26 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs200966618, COSV61328156; called by muse, mutect2, varscan2
- MRC1 | c.1879C>G p.H627D | Missense Mutation (SNP) | VAF 20/201 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ADGRV1 | c.2130T>C p.F710= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV67984786; called by muse, mutect2
- AHRR | c.783G>A p.P261= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs781369657, COSV57085841; called by muse, mutect2, varscan2
- ATP11B | c.1806C>T p.L602= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV60028406, COSV60032057; called by muse, mutect2, varscan2
- CFAP70 | c.3228C>T p.V1076= | Silent (SNP) | VAF 7/83 reads (8%) | catalogued as COSV60283067; called by muse, mutect2
- DMRTA2 | c.900G>A p.A300= | Silent (SNP) | VAF 12/146 reads (8%) | catalogued as COSV68672634; called by muse, mutect2
- EGR1 | c.1494G>A p.T498= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as rs201207618, COSV53519234; called by muse, mutect2
- EIF2AK4 | c.4254A>G p.K1418= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as COSV55468163; called by muse, mutect2
- EPHA3 | c.1320C>A p.V440= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV60704788; called by muse, mutect2, varscan2
- GSDMB | c.855C>T p.G285= (on ENST00000418519 / NM_001165958.1; = p.G263= on NM_018530.2) | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV58780688; called by muse, mutect2, varscan2
- IL37 | c.309G>A p.A103= | Silent (SNP) | VAF 24/332 reads (7%) | catalogued as rs1244883922, COSV54490942; called by muse, mutect2
- KIF3B | c.168C>G p.T56= | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as COSV65227531; called by muse, mutect2
- LDLR | c.2223A>T p.T741= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV52943173; called by muse, mutect2
- LYSMD1 | c.60G>A p.R20= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as COSV54860580; called by muse, mutect2, varscan2
- OR2T4 | c.333C>T p.P111= | Silent (SNP) | VAF 22/306 reads (7%) | catalogued as COSV63543945; called by muse, mutect2
- SIGLEC11 | c.1326G>T p.L442= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV70221984; called by muse, mutect2
- TENM2 | c.3936C>G p.R1312= (on ENST00000518659 / NM_001122679.2; = p.R1073= on NM_001080428.3) | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV69125068, COSV69129531; called by muse, mutect2
- TENM4 | c.3108A>G p.A1036= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as COSV53626974; called by muse, mutect2, varscan2
- WSCD2 | c.546C>T p.G182= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1165584036, COSV54582439; called by muse, mutect2
